Somatic mutation profile of tumor specimen 0DJR1G from CCDI case PBBXJN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.2 years (1,161 days).
Specimen 0DJR1G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6afaf1a3-fc2a-4e81-8a53-989b58ec0002.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJQZG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83d90a5a-c520-4526-9743-be726988e140

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, RNA 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 69/484 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- DNAJC6 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 28/464 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs770127313, CM162042; called by muse, mutect2
- FBN3 | c.7724C>T p.S2575L | Missense Mutation (SNP) | VAF 162/369 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs771566504, COSV99561152; called by muse, mutect2, varscan2
- KCNJ14 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 23/491 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs751117592; called by muse, mutect2
- LRFN4 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 105/379 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as rs758732410, COSV58922899; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as rs150912590; called by muse, mutect2, varscan2
- NT5C1B | c.48G>T p.R16S | Missense Mutation (SNP) | VAF 46/379 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs1252267521; called by muse, mutect2, varscan2
- PLEKHG4B | c.475G>A p.G159R (on ENST00000283426; = p.G515R on NM_052909.5) | Missense Mutation (SNP) | VAF 70/436 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs150711935; called by muse, mutect2
- ZNF337 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 32/524 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs775871346; called by muse, mutect2
- INTS3 | c.422G>T p.C141F | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- PCDH11X | c.66C>T p.G22= | Silent (SNP) | VAF 40/1089 reads (4%) | called by muse, mutect2
- POTEH | c.258C>T p.H86= | Silent (SNP) | VAF 89/328 reads (27%) | catalogued as rs370869918; called by muse, varscan2
- GK | c.*24A>C | 3'UTR (SNP) | VAF 170/412 reads (41%) | called by muse, mutect2, varscan2
- LINC01036 | n.27C>T | RNA (SNP) | VAF 68/233 reads (29%) | called by muse, mutect2, varscan2
- PRPF31 | c.528-43G>A | Intron (SNP) | VAF 178/212 reads (84%) | called by muse, mutect2, varscan2
